Somatic mutation profile of tumor specimen TCGA-D1-A1O5-01A (aliquot TCGA-D1-A1O5-01A-11D-A14G-09) from TCGA case TCGA-D1-A1O5, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G1; Age at diagnosis: 61.8 years (22,580 days).
Specimen TCGA-D1-A1O5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54d0f3e4-48c7-494e-8101-36c1aa4b7fb4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A1O5-10A (Blood Derived Normal), aliquot TCGA-D1-A1O5-10A-01D-A14G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/76ae87ec-d9e8-457e-9d6f-1a8ac1e4a405

The open-access MAF lists 69 somatic variants for this specimen: 46 protein-altering or splice-affecting, 22 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 22, Frame Shift Del 2, Nonsense Mutation 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 47/61 reads (77%) | hotspot (GDC flag); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RRAS2 | c.215A>T p.Q72L | Missense Mutation (SNP) | VAF 14/41 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs113954997, COSV56329169; ClinVar: pathogenic; called by muse, varscan2
- ACRBP | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs760419396, COSV99975944; called by muse, mutect2, varscan2
- ACSL6 | c.1412C>T p.T471I (on ENST00000379240; = p.T496I on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.71); PolyPhen benign (0.021); catalogued as COSV99732830; called by muse, mutect2, varscan2
- ARID2 | c.5030G>T p.R1677L | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57608550; called by muse, mutect2, varscan2
- ATP13A3 | c.2316T>G p.I772M | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV99756411; called by muse, mutect2, varscan2
- CNGA2 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.023); catalogued as rs375875187, COSV61706410; called by muse, mutect2, varscan2
- COL26A1 | c.1025C>T p.P342L (on ENST00000313669 / NM_001278563.3; = p.P340L on NM_133457.4) | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.207); catalogued as rs748535018, COSV100561520; called by muse, mutect2
- COL6A3 | c.2809G>A p.E937K | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.353); catalogued as rs774872934, COSV99796424; called by muse, mutect2, varscan2
- DLG3 | c.1042G>A p.G348R | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.951); catalogued as rs780951527, COSV99529236; called by muse, mutect2, varscan2
- DYRK1B | c.1265C>A p.P422H | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100546451; called by muse, mutect2
- DYRK3 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199918563, COSV100895622; called by muse, mutect2, varscan2
- FAT3 | c.10613G>A p.R3538H | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs755030491, COSV53133261; called by muse, mutect2, varscan2
- FOXO1 | c.1468C>T p.R490W | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs374723626; called by muse, mutect2, varscan2
- GCSAM | c.271C>A p.H91N | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58264441; called by muse, mutect2
- GFRA1 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV62602664; called by muse, mutect2, varscan2
- HLX | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781159180, COSV100854467; called by muse, mutect2, varscan2
- IRGQ | c.715G>A p.V239M | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as rs746931911, COSV100338064; called by muse, varscan2
- KPNB1 | c.1656G>T p.L552F | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.28); catalogued as COSV51595251; called by muse, mutect2, varscan2
- MAGEB18 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV57463629, COSV57465017; called by muse, mutect2, varscan2
- METAP1 | c.985A>G p.M329V | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56443958; called by muse, mutect2, varscan2
- MME | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.92); PolyPhen benign (0.005); catalogued as COSV100852283; called by muse, mutect2, varscan2
- MYH7 | c.3635G>A p.R1212Q | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV100805750, COSV100806450; called by mutect2, varscan2
- NAV3 | c.3884C>T p.T1295M | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs189835133, COSV99887506; called by muse, mutect2, varscan2
- NCAPD3 | c.4426G>T p.A1476S | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.219); catalogued as COSV100137873; called by muse, mutect2, varscan2
- NLRP5 | c.2209C>T p.R737W | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs537471101, COSV66762321; called by muse, mutect2, varscan2
- NPAP1 | c.64C>T p.R22C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as rs1295604109, COSV61512963; called by muse, mutect2
- NPAP1 | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV100274864; called by muse, mutect2, varscan2
- PLCG2 | c.1019C>T p.S340L | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as COSV63873773; called by muse, mutect2, varscan2
- PTPRD | c.3100G>A p.V1034M | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.715); catalogued as rs1329600473, COSV100643651, COSV61945042; called by muse, mutect2, varscan2
- RPS6KA2 | c.1942G>T p.V648F | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.119); catalogued as COSV99690294; called by muse, mutect2
- RSU1 | c.791C>T p.S264L | Missense Mutation (SNP) | VAF 54/163 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as rs1474851012, COSV100590253; called by muse, mutect2, varscan2
- RTCB | c.1138G>A p.A380T | Missense Mutation (SNP) | VAF 48/161 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1431111447, COSV53278319, COSV99321946; called by muse, mutect2, varscan2
- SAMD9 | c.1093G>A p.D365N | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101180138, COSV66077561; called by muse, mutect2, varscan2
- SESN3 | c.123T>G p.S41R | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV99565280; called by muse, mutect2, varscan2
- SLC12A5 | c.1837C>T p.R613C (on ENST00000454036 / NM_001134771.2; = p.R590C on NM_020708.5) | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54804588; called by muse, mutect2, varscan2
- SLC7A6 | c.1247C>A p.P416H | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99546434; called by muse, mutect2, varscan2
- SPANXB1 | c.40G>A p.V14I | Missense Mutation (SNP) | VAF 71/221 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.12); catalogued as rs1394966113; called by muse, mutect2, varscan2
- SPANXN3 | c.71dup p.N24Kfs*2 | Frame Shift Ins (INS) | VAF 46/120 reads (38%) | catalogued as rs781940283; called by mutect2, varscan2
- SYNM | c.4121G>A p.S1374N | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.275); catalogued as COSV100018441; called by muse, mutect2
- TBKBP1 | c.766C>T p.R256W | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1443102189, COSV64654396; called by muse, mutect2, varscan2
- TMCO3 | c.1918G>A p.E640K | Missense Mutation (SNP) | VAF 56/142 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV100952280; called by muse, mutect2, varscan2
- WDR75 | c.1673G>C p.G558A | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.118); catalogued as COSV100134049; called by muse, mutect2, varscan2
- ZBTB7B | c.1164G>C p.K388N (on ENST00000292176; = p.K422N on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52692111, COSV52692260; called by muse, mutect2
- ARID1A | c.5745del p.L1915Ffs*8 | Frame Shift Del (DEL) | VAF 24/67 reads (36%) | called by mutect2, pindel, varscan2
- FRA10AC1 | c.174_178del p.E59Sfs*4 | Frame Shift Del (DEL) | VAF 49/70 reads (70%) | called by mutect2, pindel, varscan2
- CD300E | c.162C>T p.Y54= | Silent (SNP) | VAF 31/73 reads (42%) | catalogued as rs111412583; called by muse, mutect2, varscan2
- CELSR1 | c.3174C>A p.A1058= | Silent (SNP) | VAF 3/51 reads (6%) | catalogued as COSV53097860; called by muse, mutect2
- CLPTM1 | c.417C>T p.G139= | Silent (SNP) | VAF 33/77 reads (43%) | catalogued as rs761786489, COSV100493646; called by muse, mutect2, varscan2
- CNTD1 | c.351C>T p.V117= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as COSV100162050; called by muse, mutect2, varscan2
- COPA | c.736C>A p.R246= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV54109756, COSV99614808; called by muse, mutect2
- EIF5 | c.1023C>T p.Y341= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as rs375443615; called by muse, mutect2, varscan2
- ELAPOR1 | c.2712C>T p.T904= | Silent (SNP) | VAF 29/59 reads (49%) | catalogued as COSV100884408; called by muse, mutect2, varscan2
- GUCY2C | c.9G>T p.T3= | Silent (SNP) | VAF 32/65 reads (49%) | catalogued as COSV99663114; called by muse, mutect2, varscan2
- IFT140 | c.3060C>T p.Y1020= | Silent (SNP) | VAF 30/90 reads (33%) | catalogued as rs545658252, COSV54152313; called by muse, mutect2, varscan2
- MYO5C | c.1923G>C p.A641= | Silent (SNP) | VAF 26/75 reads (35%) | catalogued as COSV99954200; called by muse, mutect2, varscan2
- PCDH17 | c.663T>A p.P221= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV100931460; called by muse, mutect2, varscan2
- PKNOX1 | c.585G>A p.A195= | Silent (SNP) | VAF 16/27 reads (59%) | catalogued as rs199928026, COSV99372680; called by muse, varscan2
- POLDIP3 | c.684C>A p.T228= | Silent (SNP) | VAF 8/81 reads (10%) | catalogued as COSV52808234; called by muse, mutect2
- PPIC | c.270C>T p.V90= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as rs770363735, COSV100120540; called by muse, mutect2
- PTPN1 | c.630C>T p.P210= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as rs745951097, COSV100860568; called by muse, mutect2, varscan2
- RAD51D | c.843C>T p.I281= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as rs754455433, COSV100238993; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCRN2 | c.291C>T p.N97= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as rs374764950, COSV51635007; called by muse, mutect2
- SIPA1L1 | c.4683C>T p.H1561= | Silent (SNP) | VAF 9/88 reads (10%) | catalogued as rs767436474, COSV100665196; called by muse, mutect2, varscan2
- TGOLN2 | c.36C>A p.V12= | Silent (SNP) | VAF 5/97 reads (5%) | catalogued as rs1399905400, COSV56405790; called by muse, mutect2
- TTI1 | c.1890G>A p.Q630= | Silent (SNP) | VAF 28/83 reads (34%) | catalogued as COSV65060898; called by muse, mutect2, varscan2
- XYLT2 | c.1626C>T p.D542= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs766559599, COSV50016989; ClinVar: likely benign; called by muse, varscan2
- ZNF668 | c.1065G>A p.A355= | Silent (SNP) | VAF 17/105 reads (16%) | catalogued as rs764641491, COSV56218832; called by muse, mutect2, varscan2
- FARP1 | c.171+31118C>T | Intron (SNP) | VAF 24/61 reads (39%) | catalogued as rs1439883788, COSV100129764; called by muse, mutect2, varscan2
